Somatic mutation profile of tumor specimen TCGA-P5-A5F0-01A (aliquot TCGA-P5-A5F0-01A-11D-A289-08) from TCGA case TCGA-P5-A5F0, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 33.3 years (12,157 days).
Specimen TCGA-P5-A5F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 341fe01a-b26f-4d2c-a40f-cee75618793b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5F0-10A (Blood Derived Normal), aliquot TCGA-P5-A5F0-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5416dd89-ff8a-47e6-b5df-58431ca31084

The open-access MAF lists 30 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 20, Nonsense Mutation 3, Silent 3, In Frame Del 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | hotspot (GDC flag); catalogued as COSV50546815, COSV50546856, COSV50551122; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.303); catalogued as rs1476721052, COSV55285273; called by muse, mutect2, varscan2
- CEP63 | c.1658A>T p.K553M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59674234; called by muse, mutect2, varscan2
- CIC | c.3337C>T p.Q1113* | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | catalogued as COSV50546825; called by muse, mutect2
- DNAH6 | c.1646T>G p.L549* | Nonsense Mutation (SNP) | VAF 45/153 reads (29%) | catalogued as COSV52848809; called by muse, mutect2, varscan2
- EPHA4 | c.2096C>A p.T699K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026108; called by muse, mutect2, varscan2
- GNAI1 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV63521587; called by muse, mutect2
- GPR15 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs202120393, COSV52519965; called by mutect2, varscan2
- HADHA | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 169/513 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV66106241; called by muse, mutect2, varscan2
- HRNR | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368316243; called by muse, mutect2, varscan2
- NACA2 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs758594535, COSV71713068; called by muse, mutect2, varscan2
- NLRP3 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60219459; called by muse, mutect2, varscan2
- OR4C16 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs768595930, COSV58940480; called by muse, mutect2, varscan2
- PCDHAC1 | c.10T>C p.C4R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV53836313; called by muse, mutect2, varscan2
- PKN3 | c.1818C>G p.C606W | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52574790, COSV52576713; called by muse, mutect2
- PLK1 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 60/651 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756845433, COSV55620546, COSV55622263; called by muse, mutect2
- POU2AF1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV67576872; called by muse, mutect2, varscan2
- PSPH | c.417T>G p.F139L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV51908810, COSV99304360; called by muse, mutect2, varscan2
- SPATA13 | c.336C>G p.N112K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57975897; called by muse, mutect2, varscan2
- TEAD1 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57560923; called by muse, mutect2
- UTRN | c.5075G>T p.R1692L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201062311, COSV62328236, COSV62335454; called by muse, mutect2, varscan2
- CCT8L2 | c.864_869delinsC p.G289* | Frame Shift Del (DEL) | VAF 33/301 reads (11%) | called by pindel, varscan2*
- CIC | c.2697del p.A900Pfs*24 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.1360_1362del p.N454del | In Frame Del (DEL) | VAF 11/119 reads (9%) | called by mutect2, pindel
- ZFX | c.2034_2036del p.K679del | In Frame Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- GRAMD1A | c.783C>T p.D261= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV58765693; called by muse, mutect2, varscan2
- ITIH5 | c.585G>A p.A195= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as rs772428688, COSV56896641; called by muse, mutect2, varscan2
- USP8 | c.870G>C p.L290= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV56162028; called by muse, mutect2, varscan2
